Somatic mutation profile of tumor specimen TCGA-05-4395-01A (aliquot TCGA-05-4395-01A-01D-1265-08) from TCGA case TCGA-05-4395, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 76.6 years (27,971 days).
Specimen TCGA-05-4395-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83798b8a-d1bf-4e49-927c-b584f9dc576f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4395-10A (Blood Derived Normal), aliquot TCGA-05-4395-10A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/368ec743-957f-4599-8627-aa1a8e871056

The open-access MAF lists 284 somatic variants for this specimen: 203 protein-altering or splice-affecting, 73 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 178, Silent 73, Nonsense Mutation 19, Splice Site 3, In Frame Del 2, RNA 2, Intron 2, 3'UTR 2, 5'UTR 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 15/59 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705661, COSV66706270; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 20/32 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 25/43 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.6118A>C p.K2040Q | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.101); catalogued as COSV66066181; called by muse, mutect2, varscan2
- ABCA13 | c.592G>T p.G198C | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV70028479; called by muse, mutect2, varscan2
- ABCA3 | c.1915C>T p.Q639* | Nonsense Mutation (SNP) | VAF 68/142 reads (48%) | catalogued as COSV57050926, COSV57053445; called by muse, mutect2, varscan2
- ACSM5 | c.554C>A p.S185Y | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.736); catalogued as COSV59371289; called by muse, mutect2, varscan2
- ADAMTS2 | c.2486C>T p.S829L | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs1226951327, COSV52370863, COSV52383930; called by muse, mutect2, varscan2
- ADAMTS20 | c.1945G>T p.G649C | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.357); catalogued as COSV67131243; called by muse, mutect2, varscan2
- ADGRL2 | c.3574G>T p.A1192S | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs781431355, COSV99589211; called by muse, mutect2, varscan2
- AHNAK2 | c.10434C>G p.F3478L | Missense Mutation (SNP) | VAF 134/264 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.189); catalogued as COSV60912170, COSV60915047; called by muse, mutect2, varscan2
- ALX4 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.585); catalogued as COSV61326381; called by muse, mutect2, varscan2
- AREL1 | c.905A>G p.Y302C | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV62666409; called by muse, mutect2, varscan2
- ASXL3 | c.5207C>A p.S1736* | Nonsense Mutation (SNP) | VAF 21/40 reads (53%) | catalogued as COSV52465648; called by muse, mutect2, varscan2
- ATP10B | c.2828C>A p.T943K | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV59151487; called by muse, mutect2, varscan2
- ATP5F1B | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.494); catalogued as COSV56260656, COSV56260966; called by muse, mutect2, varscan2
- BCAN | c.2044G>T p.D682Y | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV100228654, COSV61256811; called by muse, mutect2, varscan2
- BPTF | c.702G>T p.E234D | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.875); catalogued as COSV58837067; called by muse, mutect2, varscan2
- BTBD16 | c.233G>T p.G78V | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.036); catalogued as COSV53262957; called by muse, mutect2, varscan2
- C14orf39 | c.346T>C p.C116R | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV58781856; called by muse, mutect2, varscan2
- C4orf3 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.891); catalogued as COSV67581702, COSV67582049; called by muse, mutect2, varscan2
- C7 | c.2260A>T p.N754Y | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV57474210; called by muse, mutect2, varscan2
- CARNS1 | c.2056C>T p.R686W | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs774158458, COSV57049803; called by muse, mutect2, varscan2
- CC2D2B | c.116C>A p.S39Y | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0.206); catalogued as COSV60357928; called by muse, mutect2, varscan2
- CCDC173 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV71653448; called by muse, mutect2, varscan2
- CD47 | c.190G>C p.D64H | Missense Mutation (SNP) | VAF 83/122 reads (68%) | SIFT tolerated (0.22); PolyPhen benign (0.423); catalogued as COSV62527124; called by muse, mutect2, varscan2
- CD6 | c.1669C>T p.H557Y | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV57838068; called by muse, mutect2, varscan2
- CDK1 | c.407T>A p.I136N | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57349540; called by muse, varscan2
- CEACAM18 | c.892G>T p.V298L | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.204); catalogued as COSV67282822; called by muse, mutect2, varscan2
- CELSR3 | c.2378T>C p.I793T | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50858364; called by muse, mutect2, varscan2
- CFAP221 | c.1731+1G>A p.X577_splice | Splice Site (SNP) | VAF 23/96 reads (24%) | catalogued as COSV54657285; called by muse, mutect2, varscan2
- CFAP65 | c.2039C>A p.T680N | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58560875, COSV58561625; called by muse, mutect2, varscan2
- CHST5 | c.809G>T p.S270I | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765694646, COSV60339026; called by muse, mutect2, varscan2
- CLEC17A | c.815C>T p.T272I | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV60427706; called by muse, mutect2, varscan2
- CLEC4F | c.1264C>T p.Q422* | Nonsense Mutation (SNP) | VAF 30/67 reads (45%) | catalogued as COSV55479312; called by muse, mutect2, varscan2
- COL11A1 | c.652-1G>T p.X218_splice | Splice Site (SNP) | VAF 11/41 reads (27%) | catalogued as COSV100618514, COSV62182042; called by mutect2, varscan2
- COL20A1 | c.173T>A p.V58E | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV58917008; called by muse, mutect2, varscan2
- COL5A2 | c.2083C>G p.Q695E | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV66409662; called by muse, mutect2, varscan2
- COL6A2 | c.2145C>G p.I715M | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100153567; called by muse, mutect2, varscan2
- CPVL | c.1306G>T p.G436C | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99605820; called by muse, varscan2
- CRIM1 | c.1348G>T p.G450W | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54863849; called by muse, mutect2, varscan2
- CSMD2 | c.3271C>A p.L1091M | Missense Mutation (SNP) | VAF 83/375 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53911010; called by muse, mutect2, varscan2
- CSMD3 | c.1517C>T p.S506L (on ENST00000297405 / NM_001363185.1; = p.S402L on NM_052900.3) | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as COSV99834768; called by muse, mutect2, varscan2
- CSRNP3 | c.145A>C p.T49P | Missense Mutation (SNP) | VAF 74/141 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV58778400; called by muse, mutect2, varscan2
- CTNNA3 | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201810511; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUL1 | c.2272G>C p.E758Q | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57388522; called by muse, mutect2, varscan2
- DBN1 | c.1309G>T p.E437* | Nonsense Mutation (SNP) | VAF 24/96 reads (25%) | catalogued as COSV52789513; called by muse, mutect2
- DBN1 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV52789536; called by muse, mutect2, varscan2
- DEPDC4 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 55/160 reads (34%) | catalogued as rs746274385, COSV54553623; called by muse, mutect2, varscan2
- DLC1 | c.2596C>T p.R866C (on ENST00000276297 / NM_001348081.2; = p.R429C on NM_006094.5) | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as COSV52303370; called by muse, mutect2, varscan2
- DLL4 | c.104A>G p.Q35R | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV51062570; called by muse, mutect2, varscan2
- DMBT1 | c.6656C>T p.S2219F (on ENST00000338354 / NM_001377530.1; = p.S1462F on NM_004406.3) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV57543612; called by muse, mutect2, varscan2
- DMRT3 | c.1179C>A p.N393K | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV51904445; called by muse, mutect2, varscan2
- DNAJC2 | c.406G>C p.D136H | Missense Mutation (SNP) | VAF 18/340 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50790432; called by muse, mutect2
- DNMBP | c.3393C>G p.F1131L | Missense Mutation (SNP) | VAF 97/194 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); catalogued as COSV60624932; called by muse, mutect2, varscan2
- DOCK5 | c.1747A>G p.K583E | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT tolerated (0.42); PolyPhen benign (0.407); catalogued as COSV52401437; called by muse, mutect2, varscan2
- DPF2 | c.966G>T p.W322C | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52889228; called by muse, mutect2
- DSCAM | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 79/121 reads (65%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as COSV68638198, COSV68657536; called by muse, mutect2, varscan2
- EDDM3B | c.338G>T p.S113I | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.251); catalogued as COSV100460822; called by muse, mutect2, varscan2
- EML2 | c.911G>T p.R304L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as rs190064158, COSV55597814; called by muse, mutect2, varscan2
- EPN2 | c.1180G>T p.G394W | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100127601; called by muse, mutect2, varscan2
- EPS8L3 | c.1646G>T p.R549M (on ENST00000361965 / NM_133181.4; = p.R519M on NM_024526.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV62609455; called by muse, mutect2, varscan2
- FANK1 | c.977T>C p.V326A | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as rs754046067, COSV64129026; called by muse, mutect2, varscan2
- FBH1 | c.1292C>T p.S431F (on ENST00000362091 / NM_178150.3; = p.S482F on NM_032807.4) | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV62982524; called by muse, mutect2, varscan2
- FBXL7 | c.655G>T p.V219F | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV61645734; called by muse, mutect2, varscan2
- FEZF1 | c.687C>A p.Y229* | Nonsense Mutation (SNP) | VAF 80/131 reads (61%) | catalogued as COSV58658718; called by muse, mutect2, varscan2
- FNDC11 | c.828C>A p.N276K | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV100918798; called by muse, mutect2, varscan2
- GABRA4 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV51925449, COSV51927394; called by muse, mutect2, varscan2
- GBP6 | c.99G>C p.K33N | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as COSV100969605, COSV65011452; called by muse, mutect2, varscan2
- GLI1 | c.1493T>G p.L498R | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57361731; called by muse, mutect2, varscan2
- GLOD5 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV100297448, COSV100297516; called by muse, mutect2, varscan2
- GLRA1 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV51012399, COSV51017926; called by muse, mutect2, varscan2
- GRM7 | c.1876C>G p.R626G | Missense Mutation (SNP) | VAF 80/152 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63142847, COSV63157383; called by muse, mutect2, varscan2
- GZMB | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV53541304; called by muse, mutect2, varscan2
- HFM1 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as rs1557484453, COSV54026905; called by muse, mutect2, varscan2
- HHAT | c.1454C>T p.A485V | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.3); catalogued as COSV54798691; called by muse, mutect2, varscan2
- HNRNPM | c.1346G>T p.R449L | Missense Mutation (SNP) | VAF 69/126 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55313116, COSV55313611; called by muse, mutect2, varscan2
- HRNR | c.6107C>G p.S2036* | Nonsense Mutation (SNP) | VAF 50/1489 reads (3%) | catalogued as COSV64257773; called by muse, mutect2
- HTRA4 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.231); catalogued as COSV56759332; called by muse, mutect2, varscan2
- IDUA | c.1681C>T p.Q561* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as rs752800292, CM034103, COSV99925975; called by muse, mutect2, varscan2
- IL31 | c.354T>A p.D118E | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0.37); catalogued as COSV65476314; called by muse, mutect2, varscan2
- ISCU | c.241G>A p.E81K (on ENST00000311893 / NM_213595.4; = p.E56K on NM_014301.4) | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.052); catalogued as rs991905634, COSV57207267; called by muse, mutect2, varscan2
- ITPR2 | c.4163G>A p.G1388E | Missense Mutation (SNP) | VAF 170/235 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772647906, COSV67269177; called by muse, mutect2, varscan2
- JAKMIP3 | c.1643C>T p.A548V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs374576124; called by muse, mutect2, varscan2
- JRK | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs192430225, COSV70629834; called by muse, mutect2, varscan2
- KAZN | c.1232G>T p.S411I | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as COSV101055703; called by muse, mutect2, varscan2
- KEAP1 | c.1436A>G p.D479G | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV50282777; called by muse, mutect2, varscan2
- KIAA0408 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 61/105 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100846925; called by muse, mutect2, varscan2
- KIF2B | c.1418A>G p.K473R | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.78); catalogued as rs1026861527, COSV52130328; called by muse, mutect2, varscan2
- LAMA3 | c.5516A>C p.Q1839P (on ENST00000313654 / NM_198129.4; = p.Q230P on NM_000227.6) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV52534433; called by muse, mutect2
- LRP1B | c.11608G>A p.D3870N | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.282); catalogued as COSV67218165, COSV67232755; called by muse, varscan2
- LRP1B | c.10969G>T p.D3657Y | Missense Mutation (SNP) | VAF 59/344 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67218169; called by muse, mutect2, varscan2
- LRP2 | c.484C>G p.Q162E | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV55540920; called by muse, mutect2, varscan2
- LY96 | c.110G>T p.C37F | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99514417; called by muse, mutect2, varscan2
- MAP4 | c.1847C>G p.S616* | Nonsense Mutation (SNP) | VAF 103/156 reads (66%) | catalogued as COSV64239514; called by muse, mutect2, varscan2
- MBNL3 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1320556009, COSV63730571; called by muse, mutect2, varscan2
- MED13L | c.5456C>T p.A1819V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); catalogued as rs1243964774, COSV56116406; called by muse, mutect2, varscan2
- MIA2 | c.769C>G p.L257V | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.278); catalogued as COSV54492981; called by muse, mutect2, varscan2
- MIA2 | c.1756C>T p.H586Y | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV54491053; called by muse, mutect2, varscan2
- MLXIP | c.2523C>G p.I841M | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV59835244; called by muse, mutect2, varscan2
- MSANTD3 | c.803A>G p.N268S | Missense Mutation (SNP) | VAF 50/64 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV100614699; called by muse, mutect2, varscan2
- MSL1 | c.1423G>A p.V475I (on ENST00000398532 / NM_001365919.1; = p.V212I on NM_001012241.2) | Missense Mutation (SNP) | VAF 63/236 reads (27%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV100278124; called by muse, mutect2, varscan2
- MUC16 | c.5660C>G p.S1887C | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as COSV67448522, COSV67464939; called by muse, mutect2
- MXRA5 | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV54234756; called by muse, mutect2, varscan2
- MYCL | c.692G>T p.R231M | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.409); catalogued as COSV65694045; called by muse, mutect2
- MYO1B | c.2836G>C p.E946Q (on ENST00000304164; = p.E888Q on NM_012223.5) | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV58430765; called by muse, varscan2
- NAIP | c.462G>T p.M154I | Missense Mutation (SNP) | VAF 21/399 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV52001354, COSV52003556; called by muse, mutect2
- NBAS | c.3421A>G p.M1141V | Missense Mutation (SNP) | VAF 122/234 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as rs752655971, COSV55721424; called by muse, mutect2, varscan2
- NEU4 | c.310G>A p.A104T (on ENST00000391969 / NM_001167602.3; = p.A116T on NM_080741.4) | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.464); catalogued as rs758930258, COSV57990312; called by muse, mutect2, varscan2
- NMUR2 | c.452C>G p.P151R | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54919195; called by muse, mutect2, varscan2
- NPAP1 | c.1553C>A p.S518Y | Missense Mutation (SNP) | VAF 144/239 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV61506873; called by muse, mutect2, varscan2
- NRAP | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as COSV63490515; called by muse, mutect2, varscan2
- NRIP2 | c.153G>C p.M51I | Missense Mutation (SNP) | VAF 36/452 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV61701528; called by muse, mutect2
- NRK | c.2743G>A p.E915K | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV54591599, COSV99078914; called by muse, mutect2, varscan2
- NTRK3 | c.926G>T p.S309I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as COSV58121762; called by muse, mutect2
- NUF2 | c.1082A>T p.K361M | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV54843847; called by muse, mutect2, varscan2
- NXPE1 | c.559G>C p.E187Q (on ENST00000424269; = p.E45Q on NM_152315.5) | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99320472; called by muse, mutect2, varscan2
- OLAH | c.478G>T p.G160* (on ENST00000378228 / NM_001039702.3; = p.G213* on NM_018324.3) | Nonsense Mutation (SNP) | VAF 29/84 reads (35%) | catalogued as rs1456578234, COSV65492354; called by muse, mutect2, varscan2
- OR12D2 | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101011214, COSV65827861; called by muse, mutect2
- OR2AG2 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.417); catalogued as COSV58455106; called by muse, mutect2, varscan2
- OR2T4 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 72/275 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV63543323, COSV63543976, COSV63545316; called by muse, mutect2, varscan2
- OR52E4 | c.172C>G p.H58D | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57624716; called by muse, mutect2, varscan2
- OR5AN1 | c.457G>A p.G153S | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV100004342; called by muse, mutect2, varscan2
- OR5H15 | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 142/247 reads (57%) | catalogued as COSV62947283, COSV62947958; called by muse, mutect2, varscan2
- OR6T1 | c.172C>A p.Q58K | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as rs1266269412, COSV100189974; called by muse, mutect2, varscan2
- OSBPL10 | c.615G>T p.Q205H | Missense Mutation (SNP) | VAF 44/61 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV67339209; called by muse, mutect2, varscan2
- OTOGL | c.4138G>T p.A1380S (on ENST00000547103; = p.A1371S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV101509274; called by muse, mutect2, varscan2
- PBXIP1 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs144138798, COSV63776796; called by muse, mutect2, varscan2
- PCDH15 | c.3161T>C p.M1054T | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV57308406; called by muse, mutect2, varscan2
- PDCD11 | c.3370G>C p.E1124Q | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as COSV63933940; called by muse, mutect2, varscan2
- PDE10A | c.1439G>T p.G480V | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated (0.6); PolyPhen benign (0.054); catalogued as COSV63096430; called by muse, mutect2, varscan2
- PIM3 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as COSV62259625; called by muse, mutect2, varscan2
- PLCG1 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.778); catalogued as COSV54818481; called by muse, mutect2, varscan2
- PLEKHG4B | c.3626C>T p.S1209L (on ENST00000283426; = p.S1565L on NM_052909.5) | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.045); catalogued as rs754710502, COSV52047287; called by muse, mutect2, varscan2
- PNLIPRP1 | c.1063+1G>T p.X355_splice | Splice Site (SNP) | VAF 12/65 reads (18%) | catalogued as COSV62611778, COSV62612038; called by muse, mutect2, varscan2
- PODN | c.295G>T p.V99L (on ENST00000395871; = p.V51L on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV57013497; called by muse, mutect2, varscan2
- POLE | c.2949G>C p.K983N | Missense Mutation (SNP) | VAF 113/326 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57680024; called by muse, mutect2, varscan2
- POU2F2 | c.645C>G p.I215M (on ENST00000526816 / NM_001207025.3; = p.I199M on NM_002698.5) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60762608; called by muse, varscan2
- PPARGC1B | c.2069G>T p.G690V | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58529135; called by muse, mutect2, varscan2
- PPFIA2 | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV61031821; called by muse, mutect2, varscan2
- PRMT8 | c.716G>T p.W239L | Missense Mutation (SNP) | VAF 532/732 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV54213990; called by muse, mutect2, varscan2
- PTPRB | c.629C>A p.P210H | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.007); catalogued as COSV100547251; called by muse, mutect2, varscan2
- QSER1 | c.4743G>T p.M1581I (on ENST00000399302; = p.M1710I on NM_001076786.3) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67900513; called by muse, varscan2
- RBM10 | c.1973G>A p.W658* | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | catalogued as COSV100237811; called by muse, mutect2, varscan2
- RBM10 | c.1974G>T p.W658C | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100237812; called by muse, mutect2, varscan2
- RNASE12 | c.19A>G p.I7V | Missense Mutation (SNP) | VAF 69/122 reads (57%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV100250530; called by muse, mutect2, varscan2
- RNF130 | c.351G>C p.E117D | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV56150453; called by muse, mutect2, varscan2
- RUNX1T1 | c.1385C>A p.T462K (on ENST00000265814 / NM_001198628.1; = p.T435K on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as COSV56146487; called by muse, mutect2, varscan2
- SDK1 | c.3727G>A p.E1243K | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as COSV67368239; called by muse, mutect2, varscan2
- SETBP1 | c.2768T>A p.I923N | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0.347); catalogued as COSV56321701; called by muse, mutect2, varscan2
- SETD3 | c.794G>T p.R265L | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.334); catalogued as COSV59284357; called by muse, mutect2, varscan2
- SF3B3 | c.995C>A p.T332N | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100209881; called by muse, mutect2, varscan2
- SIM1 | c.1579C>A p.H527N | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV53491984; called by muse, mutect2, varscan2
- SLC41A2 | c.390A>T p.L130F | Missense Mutation (SNP) | VAF 114/277 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs754453323, COSV51604825; called by muse, mutect2, varscan2
- SLC45A2 | c.1186G>T p.G396* | Nonsense Mutation (SNP) | VAF 53/171 reads (31%) | catalogued as COSV56871742; called by muse, varscan2
- SLC6A17 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as COSV58993111; called by muse, mutect2, varscan2
- SLC9A2 | c.1661C>G p.S554C | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as COSV52131852; called by muse, mutect2, varscan2
- SLIT2 | c.2782A>T p.K928* | Nonsense Mutation (SNP) | VAF 101/283 reads (36%) | catalogued as COSV56571881; called by muse, mutect2, varscan2
- SLITRK3 | c.1630G>T p.V544L | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV53847670, COSV53848372; called by muse, mutect2, varscan2
- SNTG1 | c.634C>T p.L212F | Missense Mutation (SNP) | VAF 142/253 reads (56%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.979); catalogued as COSV52442577; called by muse, mutect2, varscan2
- SORCS3 | c.2323G>T p.A775S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1002406584, COSV63794998; called by muse, mutect2, varscan2
- SPEN | c.8989G>A p.E2997K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.766); catalogued as COSV65361634; called by muse, mutect2, varscan2
- STK11 | c.166G>T p.G56W | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58823539; called by muse, mutect2, varscan2
- STXBP1 | c.712G>C p.D238H | Missense Mutation (SNP) | VAF 50/84 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64813129, COSV64815293; called by muse, mutect2, varscan2
- SVEP1 | c.5189G>T p.C1730F | Missense Mutation (SNP) | VAF 90/128 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52839131; called by muse, mutect2, varscan2
- SYN3 | c.520G>T p.G174W | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV60508081; called by muse, mutect2, varscan2
- SYTL1 | c.1477G>A p.E493K (on ENST00000543823; = p.E481K on NM_032872.3) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1246156537, COSV58871759; called by muse, mutect2
- TANC1 | c.1609G>T p.A537S | Missense Mutation (SNP) | VAF 161/282 reads (57%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.473); catalogued as COSV55083477, COSV55087926; called by muse, mutect2, varscan2
- TAS2R13 | c.866G>C p.R289T | Missense Mutation (SNP) | VAF 27/257 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.145); catalogued as rs745325047, COSV101183742; called by muse, mutect2, varscan2
- TBX15 | c.1490G>T p.G497V (on ENST00000369429 / NM_001330677.2; = p.G391V on NM_152380.3) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.264); catalogued as COSV52871059; called by muse, mutect2, varscan2
- TENM4 | c.3653C>A p.P1218H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53611750, COSV53627735; called by muse, mutect2, varscan2
- TEX15 | c.1344A>T p.E448D (on ENST00000256246; = p.E831D on NM_001350162.2) | Missense Mutation (SNP) | VAF 105/185 reads (57%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV56346268; called by muse, mutect2, varscan2
- TMED3 | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV100229973; called by muse, mutect2, varscan2
- TNK2 | c.463G>T p.V155L | Missense Mutation (SNP) | VAF 39/57 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV57369190; called by muse, mutect2, varscan2
- TPCN2 | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200218534; called by muse, mutect2, varscan2
- TRIM7 | c.914C>G p.S305C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.747); catalogued as COSV51242306; called by muse, mutect2, varscan2
- TRIP12 | c.1853C>T p.S618L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV52263831; called by muse, mutect2, varscan2
- TUT4 | c.4192C>T p.Q1398* | Nonsense Mutation (SNP) | VAF 31/56 reads (55%) | catalogued as COSV57112188, COSV57113878; called by muse, mutect2, varscan2
- TXNDC16 | c.1555A>T p.K519* | Nonsense Mutation (SNP) | VAF 34/67 reads (51%) | catalogued as COSV55984621; called by muse, mutect2, varscan2
- UBE4A | c.1769C>T p.S590F (on ENST00000252108 / NM_001204077.2; = p.S597F on NM_004788.4) | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV52803956, COSV52804120; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3160C>T p.P1054S | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV54437255; called by muse, mutect2, varscan2
- UQCC1 | c.862A>C p.K288Q | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.925); catalogued as COSV62902472; called by muse, mutect2, varscan2
- USP38 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 56/97 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61025853; called by muse, mutect2, varscan2
- USP7 | c.2487G>T p.R829S | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.237); catalogued as COSV61214582; called by muse, mutect2, varscan2
- VCAN | c.391G>T p.D131Y | Missense Mutation (SNP) | VAF 64/126 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766885058, COSV54104853; called by muse, mutect2, varscan2
- VCAN | c.4721T>A p.V1574E | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as COSV54104862; called by muse, mutect2, varscan2
- VSIG2 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52518489; called by muse, mutect2, varscan2
- XIRP2 | c.7199G>A p.S2400N (on ENST00000628543; = p.S2575N on NM_152381.6) | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV54699352; called by muse, mutect2, varscan2
- ZBED9 | c.3138G>T p.M1046I | Missense Mutation (SNP) | VAF 64/110 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.38); catalogued as COSV101509430, COSV71729394; called by muse, mutect2, varscan2
- ZBTB10 | c.1897G>C p.D633H | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV66947426; called by muse, mutect2, varscan2
- ZCCHC7 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60957312; called by muse, mutect2, varscan2
- ZDHHC6 | c.1039C>A p.P347T | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV100634586; called by muse, mutect2, varscan2
- ZFHX4 | c.1166C>A p.S389* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | catalogued as COSV99262910, COSV99264559; called by mutect2, varscan2
- ZMYM6 | c.1010C>G p.S337* | Nonsense Mutation (SNP) | VAF 15/68 reads (22%) | catalogued as COSV64120441, COSV64120889; called by muse, mutect2, varscan2
- ZNF623 | c.985A>T p.I329F | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.085); catalogued as COSV71697178; called by muse, mutect2, varscan2
- ZNF624 | c.1141A>G p.I381V | Missense Mutation (SNP) | VAF 77/116 reads (66%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs755241393, COSV100257260; called by muse, mutect2, varscan2
- ZNF831 | c.3521T>G p.F1174C | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64040018; called by muse, mutect2, varscan2
- ZNF85 | c.1246C>A p.H416N | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60214520; called by muse, mutect2, varscan2
- C1orf35 | c.615_620del p.D205_K206del | In Frame Del (DEL) | VAF 23/55 reads (42%) | called by mutect2, pindel, varscan2
- IGLV3-9 | c.83C>G p.S28* | Nonsense Mutation (SNP) | VAF 20/29 reads (69%) | called by muse, mutect2, varscan2
- MEAF6 | c.155_175del p.Q52_I58del | In Frame Del (DEL) | VAF 36/136 reads (26%) | called by mutect2, pindel, varscan2
- NLRP5 | c.1268_1269insCC p.P424Lfs*6 | Frame Shift Ins (INS) | VAF 11/27 reads (41%) | called by mutect2, pindel, varscan2
- TRAV12-2 | c.52G>C p.V18L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ACHE | c.1155C>T p.I385= | Silent (SNP) | VAF 43/133 reads (32%) | catalogued as COSV99574127; called by muse, mutect2, varscan2
- ACSM3 | c.531A>G p.L177= | Silent (SNP) | VAF 37/118 reads (31%) | catalogued as COSV99184510; called by muse, mutect2, varscan2
- AIF1L | c.411A>T p.P137= | Silent (SNP) | VAF 31/57 reads (54%) | catalogued as COSV99908184; called by muse, mutect2
- AP002512.3 | c.627C>A p.A209= | Silent (SNP) | VAF 43/98 reads (44%) | catalogued as COSV99687957; called by muse, mutect2, varscan2
- APOB | c.4662C>A p.I1554= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV51934898; called by muse, mutect2, varscan2
- ASPM | c.2448G>C p.L816= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as rs565764186, COSV54129640; called by muse, mutect2, varscan2
- BICC1 | c.2844C>T p.T948= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs1000478323, COSV65859424; called by muse, mutect2, varscan2
- CERS6 | c.486G>C p.T162= | Silent (SNP) | VAF 25/186 reads (13%) | catalogued as COSV59827554, COSV59830101; called by muse, mutect2, varscan2
- CLDN1 | c.450C>T p.D150= | Silent (SNP) | VAF 33/53 reads (62%) | catalogued as COSV55044025; called by muse, mutect2, varscan2
- CRB1 | c.4128G>A p.Q1376= | Silent (SNP) | VAF 99/119 reads (83%) | catalogued as COSV66340709; called by muse, mutect2, varscan2
- CRYBB1 | c.717C>T p.L239= | Silent (SNP) | VAF 41/81 reads (51%) | catalogued as rs779509832, COSV53233207; called by muse, mutect2, varscan2
- CTCF | c.822G>C p.T274= | Silent (SNP) | VAF 10/124 reads (8%) | catalogued as rs754924154, COSV50468115; called by muse, mutect2
- DNAH9 | c.8934C>A p.I2978= | Silent (SNP) | VAF 95/157 reads (61%) | catalogued as COSV52334173, COSV52348894; called by muse, mutect2, varscan2
- DST | c.7713T>C p.T2571= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV99756092; called by muse, mutect2, varscan2
- EDAR | c.39C>A p.L13= | Silent (SNP) | VAF 21/179 reads (12%) | catalogued as COSV51502699, COSV99304467; called by muse, mutect2, varscan2
- EDC4 | c.606C>T p.F202= | Silent (SNP) | VAF 64/99 reads (65%) | catalogued as rs368076076, COSV99534366; called by muse, varscan2
- EHMT1 | c.357C>G p.V119= | Silent (SNP) | VAF 80/120 reads (67%) | catalogued as COSV58374817, COSV58375383; called by muse, mutect2, varscan2
- FAT3 | c.8439C>G p.V2813= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV53108550; called by muse, mutect2, varscan2
- GALM | c.789T>A p.A263= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as COSV55371601; called by muse, mutect2, varscan2
- GUK1 | c.66G>A p.K22= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV57156119; called by muse, mutect2, varscan2
- HECTD4 | c.9963C>A p.S3321= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV66391868; called by muse, mutect2, varscan2
- IFFO1 | c.1023C>T p.C341= | Silent (SNP) | VAF 78/103 reads (76%) | catalogued as rs138562505; called by muse, mutect2, varscan2
- IGDCC3 | c.1722A>G p.G574= | Silent (SNP) | VAF 50/101 reads (50%) | catalogued as COSV60077528; called by muse, mutect2, varscan2
- LCT | c.84C>T p.F28= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV51466278; called by muse, mutect2, varscan2
- LGR5 | c.2469C>T p.F823= | Silent (SNP) | VAF 45/139 reads (32%) | catalogued as rs1263793930, COSV57004886; called by muse, mutect2, varscan2
- LOXL3 | c.1155G>A p.K385= | Silent (SNP) | VAF 57/116 reads (49%) | catalogued as COSV51207480; called by muse, mutect2, varscan2
- LPA | c.5940C>T p.A1980= | Silent (SNP) | VAF 41/67 reads (61%) | catalogued as COSV60301659; called by muse, mutect2, varscan2
- LRFN5 | c.951A>T p.A317= | Silent (SNP) | VAF 50/164 reads (30%) | catalogued as COSV53241281, COSV53255658; called by muse, mutect2, varscan2
- MACF1 | c.13275A>G p.G4425= (on ENST00000372915; = p.G2358= on NM_012090.5) | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as COSV57120506; called by muse, mutect2, varscan2
- MAGEB1 | c.159T>A p.P53= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV100974974; called by muse, mutect2, varscan2
- MAGEB3 | c.669C>A p.I223= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV64397078; called by muse, mutect2, varscan2
- MARCHF1 | c.849C>A p.P283= (on ENST00000274056; = p.P266= on NM_017923.4) | Silent (SNP) | VAF 38/60 reads (63%) | catalogued as COSV56814752; called by muse, mutect2, varscan2
- MME | c.1272G>A p.G424= | Silent (SNP) | VAF 42/200 reads (21%) | catalogued as COSV64707347; called by muse, mutect2, varscan2
- MPP2 | c.1122G>T p.R374= (on ENST00000461854 / NM_001278372.2; = p.R350= on NM_005374.5) | Silent (SNP) | VAF 42/98 reads (43%) | catalogued as rs1251821909, COSV52235714, COSV52240951; called by muse, mutect2, varscan2
- MYH7 | c.5640C>G p.R1880= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV62519114; called by muse, mutect2, varscan2
- MYO15A | c.1041G>A p.A347= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as rs527681283, COSV52753210, COSV52756478; ClinVar: likely benign; called by muse, mutect2
- NCOA3 | c.279T>C p.D93= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV59068493; called by muse, mutect2, varscan2
- NCOA6 | c.3354G>A p.P1118= | Silent (SNP) | VAF 53/138 reads (38%) | catalogued as rs761459718, COSV62863543; called by muse, mutect2, varscan2
- NYNRIN | c.3195G>T p.L1065= | Silent (SNP) | VAF 48/127 reads (38%) | catalogued as COSV66842379; called by muse, mutect2, varscan2
- OR10AD1 | c.381C>T p.I127= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV100046774; called by muse, mutect2, varscan2
- OR10K2 | c.930C>T p.S310= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV59221163; called by muse, mutect2, varscan2
- OR11H6 | c.228C>A p.P76= | Silent (SNP) | VAF 27/116 reads (23%) | catalogued as COSV59644221; called by muse, mutect2, varscan2
- OR11L1 | c.504C>T p.F168= | Silent (SNP) | VAF 63/190 reads (33%) | catalogued as COSV63314470; called by muse, mutect2, varscan2
- OR56A1 | c.549C>A p.A183= | Silent (SNP) | VAF 44/106 reads (42%) | catalogued as COSV57362595; called by muse, mutect2, varscan2
- OR7E24 | c.168G>A p.T56= | Silent (SNP) | VAF 33/51 reads (65%) | catalogued as rs767194817, COSV71702186, COSV71702213; called by muse, mutect2, varscan2
- PDILT | c.963T>A p.R321= | Silent (SNP) | VAF 53/174 reads (30%) | catalogued as COSV56701868; called by muse, mutect2, varscan2
- PDP2 | c.129C>T p.S43= | Silent (SNP) | VAF 21/192 reads (11%) | catalogued as COSV61241885; called by muse, mutect2, varscan2
- PLVAP | c.862C>A p.R288= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV53085022; called by muse, mutect2, varscan2
- PRDM10 | c.582G>C p.P194= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV58801251; called by muse, mutect2, varscan2
- PRKCA | c.120C>A p.I40= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as COSV52584352; called by muse, mutect2, varscan2
- PTPRB | c.630C>T p.P210= | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as rs765057015, COSV100547250, COSV57707333; called by muse, mutect2, varscan2
- RBFOX1 | c.786C>A p.T262= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV100302663, COSV60958161; called by muse, mutect2
- RGS10 | c.349C>T p.L117= (on ENST00000369101; = p.L111= on NM_002925.3) | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as rs1378005795, COSV64862062; called by muse, mutect2, varscan2
- S100PBP | c.339C>G p.L113= | Silent (SNP) | VAF 33/71 reads (46%) | catalogued as COSV63140122; called by muse, mutect2, varscan2
- SCN9A | c.1839G>A p.P613= | Silent (SNP) | VAF 39/98 reads (40%) | catalogued as rs565711085, COSV57609433, COSV57612255; called by muse, mutect2, varscan2
- SEPTIN1 | c.714G>A p.L238= (on ENST00000321367; = p.L191= on NM_052838.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/113 reads (35%) | catalogued as COSV58442258; called by muse, mutect2, varscan2
- SF3B3 | c.996T>A p.T332= | Silent (SNP) | VAF 22/187 reads (12%) | catalogued as COSV100209884; called by muse, mutect2, varscan2
- SH3TC1 | c.879C>T p.A293= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV55284077; called by muse, mutect2, varscan2
- SLC29A3 | c.1047C>T p.L349= | Silent (SNP) | VAF 112/262 reads (43%) | catalogued as COSV64385067; called by muse, mutect2, varscan2
- SLC35F3 | c.934T>C p.L312= (on ENST00000366617 / NM_001300845.1; = p.L381= on NM_173508.4) | Silent (SNP) | VAF 54/205 reads (26%) | catalogued as COSV100784793, COSV64019590; called by muse, mutect2, varscan2
- SLC39A9 | c.372G>A p.Q124= | Silent (SNP) | VAF 44/263 reads (17%) | catalogued as COSV50362525; called by muse, mutect2, varscan2
- SON | c.159C>T p.A53= | Silent (SNP) | VAF 54/96 reads (56%) | catalogued as COSV51657210; called by muse, mutect2, varscan2
- SPTA1 | c.3594G>A p.Q1198= | Silent (SNP) | VAF 22/142 reads (15%) | catalogued as COSV63752840; called by muse, mutect2, varscan2
- SV2B | c.1698C>G p.L566= | Silent (SNP) | VAF 37/118 reads (31%) | catalogued as rs1033712029, COSV100370757, COSV57699702; called by muse, mutect2, varscan2
- TIAM2 | c.1800C>T p.F600= | Silent (SNP) | VAF 66/135 reads (49%) | catalogued as COSV59694063; called by muse, mutect2, varscan2
- TRIM9 | c.279G>A p.Q93= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV53617074; called by muse, mutect2, varscan2
- TSHR | c.1656C>T p.L552= | Silent (SNP) | VAF 22/138 reads (16%) | catalogued as rs746360455, COSV53319677; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- USH2A | c.15444C>T p.L5148= | Silent (SNP) | VAF 39/141 reads (28%) | catalogued as COSV56367649; called by muse, mutect2, varscan2
- UTP20 | c.2118G>A p.V706= | Silent (SNP) | VAF 45/146 reads (31%) | catalogued as COSV55376875; called by muse, mutect2, varscan2
- WASHC5 | c.687G>C p.L229= | Silent (SNP) | VAF 67/118 reads (57%) | catalogued as COSV59196284; called by muse, mutect2, varscan2
- WNT2 | c.844C>A p.R282= | Silent (SNP) | VAF 72/118 reads (61%) | catalogued as COSV55410966; called by muse, mutect2, varscan2
- ZNF224 | c.135C>T p.L45= | Silent (SNP) | VAF 34/144 reads (24%) | catalogued as rs1568529744, COSV61242287; called by muse, mutect2, varscan2
- ZNF335 | c.3636G>A p.Q1212= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as rs1277670021, COSV59817721; called by muse, mutect2, varscan2
- C3P1 | n.3462G>T | RNA (SNP) | VAF 44/86 reads (51%) | called by muse, mutect2, varscan2
- CTBP2 | c.58+11325G>A | Intron (SNP) | VAF 8/45 reads (18%) | catalogued as rs762107393, COSV100456473; called by muse, mutect2, varscan2
- DEPDC5 | c.*940G>T | 3'UTR (SNP) | VAF 95/159 reads (60%) | catalogued as COSV56697191; called by muse, mutect2, varscan2
- FBXL21P | n.741G>A | RNA (SNP) | VAF 24/93 reads (26%) | catalogued as COSV51809053; called by muse, mutect2, varscan2
- MMP19 | c.*2T>A | 3'UTR (SNP) | VAF 109/256 reads (43%) | catalogued as COSV100491111; called by muse, mutect2, varscan2
- RAD51AP1 | c.-1C>T | 5'UTR (SNP) | VAF 14/154 reads (9%) | catalogued as COSV99712740; called by muse, mutect2
- RTL1 | chr14:100875080 G>T | 3'Flank (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- SYTL2 | c.1615+1278A>G | Intron (SNP) | VAF 78/203 reads (38%) | catalogued as COSV100314275; called by muse, mutect2, varscan2
